Gene-level copy-number profile of tumor specimen TCGA-AY-4071-01A from TCGA case TCGA-AY-4071, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 63.8 years (23,320 days).
Specimen TCGA-AY-4071-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.328f99f5-5c56-448a-8c0b-9382ef79198f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AY-4071-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ec6e18b4-8b21-41a4-a268-8c56590629f0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 531; copy number 1: 12; copy number 2: 7,894; copy number 3: 31,250; copy number 4: 16,004; copy number 5: 1,449; copy number 6: 1,699; copy number 7: 364; copy number 8: 45; copy number 9: 869; copy number 10: 155.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AY-4071-01A-01D-1427-01): tumor purity 0.6, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:9,480,608–9,576,275, 2 genes (within-gene range 0–3): AC092821.1, AC092821.2.
- chr15:34,373,541–34,521,791, 9 genes: ACTG1P15, GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,433 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:79,030,240–98,310,441, 242 genes, copy number 7 (broad region; genes not listed).
- chr13:80,335,976–90,231,682, 79 genes, copy number 7–8 (broad region; genes not listed).
- chr20:16,177,933–19,056,796, 72 genes, copy number 7 (broad region; genes not listed).
- chr20:21,705,659–64,313,132, 1,040 genes, copy number 7–10 (within-gene range 7–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
